Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAW0, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAW0-01A (Primary Tumor).

ICD-O-3
Carcinoma, hepatocellular NOS
Site: Liver C22.0 8170/3
JW 4/23/14

DIAGNOSIS:

Liver, total hepatectomy and liver transplantation:

Hepatocellular carcinoma, S7

- 1) Post-chemoembolization status: present *Pw TSS, patient did NOT receive chemoembolization prior to TCGA tumor procurement. BCR*
- 2) Size of tumor: 7x6x5.5cm
- 3) Gross type: nodular with perinodal extension
- 4) Satellite nodule: absent
- 5) Histologic type: trabecular and compact
- 6) Cell type: classic and clear cell group
- 7) Edmondson and Steiner's histologic grade:
The worst differentiation: 3
The major differentiation: 2
- 8) Fatty change: present (80%)
- 9) Hemorrhage/peliosis: absent
- 10) Tumor necrosis: present (90%)
- 11) Vascular invasion(microscopic): absent
- 12) Capsule formation: partial
- 13) Infiltration of capsule: absent
- 14) Septal formation: present
- 15) Involvement of a major branch of the portal vein: absent
- 16) Involvement of a major branch of the hepatic vein: absent
- 17) Bile duct invasion: absent
- 18) Serosal invasion: absent with fibrous adhesion
- 19) Intrahepatic metastasis: absent
- 20) Multicentric occurrence: absent
- 21) Pathologic stage: AJCC (pT1), (pT2)
- 22) Related biopsy: none
- 23) Additional pathologic findings
- Chronic hepatitis
- with a) no lobular activity
- b) minimal portal activity
- c) septal fibrosis
- Cirrhosis: absent
- Dysplasia: absent
- Fatty change, moderate
- Post-chemoembolization status
- with parenchymal necrosis, S6: size; 4x3x2cm
- Partial adrenal adhesion

Source: NCI Genomic Data Commons file e1baa499-65d3-4103-9806-796866d5772b (TCGA-DD-AAW0.75F8B93A-4839-4A9B-92CD-98147D025D31.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).